Somatic mutation profile of tumor specimen MP2PRT-PAVKVU-TBP1-A (aliquot MP2PRT-PAVKVU-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVKVU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (718 days).
Specimen MP2PRT-PAVKVU-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9428024-66f9-4c4f-9da5-e878c75715ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKVU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKVU-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32122437-6eab-4bef-9975-f5ee33d67e4a

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLEK2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 29/494 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs764046676, COSV99371606; called by muse, mutect2
- ELFN1 | c.2126G>A p.G709D | Missense Mutation (SNP) | VAF 41/986 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.936); called by muse, mutect2
- PLA2G12A | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 62/608 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, varscan2
- YEATS4 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT13 | c.264C>A p.G88= | Silent (SNP) | VAF 66/633 reads (10%) | called by mutect2, varscan2
